FM case AD17576 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/81607640-c9ab-4a89-837c-4e91d3d8033b

Female, 76.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
